Somatic mutation profile of tumor specimen TCGA-XJ-A83G-01A (aliquot TCGA-XJ-A83G-01A-11D-A34U-08) from TCGA case TCGA-XJ-A83G, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-XJ-A83G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e52c49e7-6c9b-48e7-9c4b-424964a6112f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XJ-A83G-10A (Blood Derived Normal), aliquot TCGA-XJ-A83G-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62758dff-487d-470f-9c10-bce5f94310d8

The open-access MAF lists 26 somatic variants for this specimen: 21 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 4, Frame Shift Del 2, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EXT1 | c.1468del p.L490Wfs*9 | Frame Shift Del (DEL) | VAF 11/89 reads (12%) | catalogued as rs886039355, CD000259; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SPOP | c.391T>G p.W131G | Missense Mutation (SNP) | VAF 11/165 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as rs1057519968, COSV61652911, COSV61653817; ClinVar: likely pathogenic; called by muse, mutect2
- ACAD10 | c.2584G>T p.D862Y | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100564353; called by muse, mutect2, varscan2
- ACSBG1 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.03); catalogued as rs143166464; called by muse, mutect2, varscan2
- AGER | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs770719664; called by muse, mutect2
- AKAP6 | c.5851G>A p.E1951K | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as rs1472135012, COSV55226177; called by muse, mutect2, varscan2
- BTBD8 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100730359; called by muse, mutect2
- DDX23 | c.455A>G p.K152R | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.899); catalogued as rs1416121539, COSV57282523; called by muse, mutect2
- EDRF1 | c.2154A>C p.L718F (on ENST00000356792 / NM_001202438.2; = p.L684F on NM_015608.2) | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV100523625; called by muse, mutect2, varscan2
- FCN1 | c.721G>A p.G241R | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as rs149439264; called by muse, mutect2, varscan2
- GBF1 | c.4964A>G p.Y1655C (on ENST00000369983 / NM_001377137.1; = p.Y1654C on NM_004193.3) | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV100890552; called by muse, mutect2, varscan2
- IGDCC3 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100031268; called by muse, mutect2, varscan2
- KIF1C | c.2887C>T p.R963C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.63); catalogued as rs768222656, COSV57906154; called by mutect2, varscan2
- MAGEA6 | c.588G>T p.M196I | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV100262876; called by muse, mutect2, varscan2
- PCDH11X | c.83A>T p.Y28F | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100012825; called by muse, mutect2, varscan2
- PTPRC | c.2593G>A p.G865R | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61406654; called by muse, mutect2, varscan2
- RIOX2 | c.1031C>T p.A344V (on ENST00000333396 / NM_001042533.2; = p.A343V on NM_032778.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs149644546; called by muse, mutect2, varscan2
- TET1 | c.4343C>A p.A1448D | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101017806, COSV101018496; called by muse, mutect2
- ITPR2 | c.4637del p.N1546Ifs*19 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | called by mutect2, pindel
- OR8G2P | c.813G>C p.R271S | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKHD1 | c.5557_5562del p.W1853_A1854del | In Frame Del (DEL) | VAF 14/83 reads (17%) | called by pindel, varscan2
- C1QC | c.537C>T p.C179= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs150732699; called by muse, mutect2, varscan2
- PAPLN | c.1017C>T p.P339= (on ENST00000554301; = p.P312= on NM_173462.4) | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as rs776818190, COSV99389950; called by muse, mutect2, varscan2
- STRA6 | c.1902C>T p.R634= | Silent (SNP) | VAF 27/139 reads (19%) | catalogued as rs551686188, COSV51434396; called by muse, mutect2, varscan2
- SUN2 | c.723C>T p.F241= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV99325682; called by muse, mutect2, varscan2
- PHACTR4 | c.17-20697G>T | Intron (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100868472; called by muse, mutect2, varscan2
